Somatic mutation profile of tumor specimen C3N-03617-03 (aliquot CPT0195330006) from CPTAC case C3N-03617, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 73.5 years (26,863 days).
Specimen C3N-03617-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) baf450a3-e6c4-42ca-a573-80499fae6b83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03617-71 (Blood Derived Normal), aliquot CPT0195430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6222c52b-d360-428a-8491-88022564cd47

The open-access MAF lists 534 somatic variants for this specimen: 345 protein-altering or splice-affecting, 169 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 310, Silent 169, Nonsense Mutation 25, Intron 11, Splice Region 5, RNA 3, Frame Shift Del 2, 5'Flank 2, 5'UTR 2, Splice Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1511G>A p.G504E (on ENST00000288602 / NM_001374244.1; = p.G464E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/350 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913348, CM086781, COSV56066746, COSV56075378; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CHAMP1 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 107/596 reads (18%) | catalogued as rs797044962, CM129412; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 70/306 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 59/379 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.3470C>T p.S1157F | Missense Mutation (SNP) | VAF 113/651 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV56848259; called by muse, mutect2, varscan2
- ACRV1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 63/389 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs758100709, COSV59754631; called by muse, mutect2, varscan2
- ACSM2A | c.1681G>A p.A561T (on ENST00000219054; = p.A482T on NM_001308169.2) | Missense Mutation (SNP) | VAF 80/407 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1054977; called by muse, mutect2, varscan2
- ACTL8 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 98/546 reads (18%) | SIFT tolerated (0.81); PolyPhen probably damaging (1); catalogued as COSV64861208; called by muse, mutect2, varscan2
- ADAMTS8 | c.1255G>A p.G419S | Missense Mutation (SNP) | VAF 74/420 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs770176841; called by muse, mutect2, varscan2
- ADGRV1 | c.5917G>A p.D1973N | Missense Mutation (SNP) | VAF 71/480 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67985325; called by muse, mutect2
- AGBL2 | c.2351G>A p.G784E | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs764754081; called by muse, mutect2, varscan2
- ALDH1B1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 106/456 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs1463116668; called by muse, mutect2, varscan2
- AMZ1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 107/646 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs201824612, COSV100406629; called by muse, mutect2, varscan2
- ANO2 | c.1805G>A p.W602* (on ENST00000356134 / NM_001278597.3; = p.W606* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 55/374 reads (15%) | catalogued as COSV59034414; called by muse, mutect2, varscan2
- B4GALNT2 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 81/508 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs187168801; called by muse, mutect2, varscan2
- BRD1 | c.2423C>T p.S808F (on ENST00000216267 / NM_001349940.1; = p.S939F on NM_001304808.3) | Missense Mutation (SNP) | VAF 70/342 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV53456408; called by muse, mutect2, varscan2
- C1orf94 | c.1673C>T p.P558L (on ENST00000488417 / NM_001134734.2; = p.P368L on NM_032884.5) | Missense Mutation (SNP) | VAF 70/444 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as COSV100975033; called by muse, mutect2, varscan2
- CAVIN3 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 113/515 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs945894091; called by muse, mutect2, varscan2
- CD1C | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 129/546 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV63806840, COSV63807957; called by muse, mutect2, varscan2
- CD33 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 106/570 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as rs1253367941, COSV51801955; called by muse, mutect2, varscan2
- CD86 | c.279G>A p.W93* (on ENST00000330540 / NM_175862.5; = p.W87* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 98/475 reads (21%) | catalogued as COSV100054264; called by muse, mutect2, varscan2
- CD93 | c.1307G>A p.G436D | Missense Mutation (SNP) | VAF 124/744 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs748218428; called by muse, mutect2, varscan2
- CDCP1 | c.2082G>A p.K694= | Splice Region (SNP) | VAF 63/318 reads (20%) | catalogued as rs1444437435, COSV56108204; called by muse, mutect2, varscan2
- CLEC19A | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs990253865; called by muse, mutect2, varscan2
- CNDP1 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 76/434 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1009635770; called by muse, mutect2, varscan2
- COL4A2 | c.4871C>T p.S1624F | Missense Mutation (SNP) | VAF 71/370 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64631437; called by muse, mutect2, varscan2
- COL5A2 | c.4088G>A p.G1363D | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761034544; called by muse, mutect2, varscan2
- COL9A3 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 143/691 reads (21%) | catalogued as rs1201247953, COSV58985033; called by muse, mutect2, varscan2
- CORIN | c.1650G>T p.Q550H | Missense Mutation (SNP) | VAF 114/540 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56691609; called by muse, mutect2, varscan2
- CR1 | c.2755C>T p.R919C | Missense Mutation (SNP) | VAF 128/776 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs761231049; called by muse, mutect2, varscan2
- CRB2 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 70/351 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758548172, COSV63505541; called by muse, mutect2, varscan2
- CSMD2 | c.4498C>T p.H1500Y | Missense Mutation (SNP) | VAF 74/445 reads (17%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV53964406; called by muse, mutect2, varscan2
- CSMD2 | c.2461G>A p.V821I | Missense Mutation (SNP) | VAF 82/493 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.425); catalogued as COSV99590779; called by muse, mutect2, varscan2
- CYP2C18 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 86/353 reads (24%) | catalogued as rs141271146; called by muse, mutect2, varscan2
- DACT2 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 103/486 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.301); catalogued as rs1045150642; called by muse, mutect2, varscan2
- DAPK1 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV63786292; called by muse, mutect2, varscan2
- DDX46 | c.1341A>G p.I447M | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1368412854; called by muse, mutect2, varscan2
- DNAH5 | c.2956C>T p.H986Y | Missense Mutation (SNP) | VAF 64/398 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99451043; called by muse, mutect2, varscan2
- DNAI3 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs953386142; called by muse, mutect2, varscan2
- DOCK3 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56546332; called by muse, mutect2, varscan2
- DSCAML1 | c.385G>A p.D129N (on ENST00000321322; = p.D69N on NM_020693.4) | Missense Mutation (SNP) | VAF 104/581 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs529321691; called by muse, mutect2, varscan2
- EGFLAM | c.1828C>T p.P610S | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59299222; called by muse, mutect2, varscan2
- ERGIC1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 101/516 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs760418745, COSV58595490; called by muse, mutect2, varscan2
- F13B | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 77/441 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs748341394, COSV66373444; called by muse, mutect2, varscan2
- FAT4 | c.14063C>T p.S4688F | Missense Mutation (SNP) | VAF 101/547 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV58690701; called by muse, mutect2, varscan2
- FBN1 | c.1951G>A p.V651M | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.605); catalogued as rs1335043561; called by muse, mutect2, varscan2
- FBN3 | c.7483C>T p.P2495S | Missense Mutation (SNP) | VAF 63/371 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs373710480; called by muse, mutect2, varscan2
- FCRL5 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 325/802 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62516962; called by muse, mutect2, varscan2
- FERMT1 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.555); catalogued as rs1466156414, COSV54090886; called by muse, mutect2, varscan2
- FGF12 | c.373C>T p.L125F (on ENST00000454309 / NM_021032.5; = p.L63F on NM_004113.6) | Missense Mutation (SNP) | VAF 71/417 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs1416073662, COSV53173890; called by muse, mutect2, varscan2
- FREM2 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 114/569 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as rs747164291, COSV54827782; called by muse, mutect2, varscan2
- FUBP3 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 83/412 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs1414817859; called by muse, mutect2, varscan2
- GGT7 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 111/723 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs758140805; called by muse, mutect2, varscan2
- GLYAT | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 117/649 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53539861; called by muse, mutect2, varscan2
- GPLD1 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 74/450 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1310782982; called by muse, mutect2, varscan2
- GRIA2 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 53/336 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs1463020369, COSV52393314; called by muse, mutect2, varscan2
- GSG1L2 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 157/666 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751121792; called by muse, mutect2, varscan2
- HIVEP3 | c.6073C>T p.P2025S | Missense Mutation (SNP) | VAF 108/646 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1252084537, COSV99912625; called by muse, mutect2, varscan2
- IGHA1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 134/1158 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as rs587723177; called by muse, mutect2, varscan2
- IGHV1-45 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs782414588; called by muse, mutect2, varscan2
- IGSF5 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 76/515 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV66029331; called by muse, mutect2
- IKZF1 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 94/516 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58787727; called by muse, mutect2, varscan2
- ILDR1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 126/643 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.339); catalogued as COSV56549679; called by muse, mutect2, varscan2
- IRF6 | c.968G>A p.W323* | Nonsense Mutation (SNP) | VAF 111/617 reads (18%) | catalogued as COSV100884011; called by muse, mutect2, varscan2
- ITGAE | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 14/464 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219285959; called by muse, mutect2
- ITPR2 | c.7181C>T p.S2394F | Missense Mutation (SNP) | VAF 85/434 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67273827; called by muse, mutect2, varscan2
- JHY | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 105/496 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56218965; called by muse, varscan2
- JMJD7-PLA2G4B | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 50/334 reads (15%) | catalogued as rs768899648; called by muse, mutect2, varscan2
- KANK4 | c.2375C>T p.S792L | Missense Mutation (SNP) | VAF 92/482 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs139968342, COSV58093499; called by muse, mutect2
- KCNH5 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 73/462 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.088); catalogued as COSV59757442; called by muse, mutect2, varscan2
- KRT6B | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 85/435 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99360713; called by muse, mutect2, varscan2
- KRT75 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 102/673 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.123); catalogued as rs139460759; called by muse, mutect2, varscan2
- KSR2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 88/473 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs889640480; called by muse, mutect2, varscan2
- LHX9 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 84/475 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61327869; called by muse, mutect2, varscan2
- LMF1 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 109/721 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs778121998, COSV51901393; called by muse, mutect2, varscan2
- LRP1 | c.5453C>T p.S1818L | Missense Mutation (SNP) | VAF 97/629 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs779355929; called by muse, mutect2, varscan2
- LRRK1 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 109/654 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52619633; called by muse, mutect2
- LSR | c.1672G>A p.E558K (on ENST00000361790; = p.E539K on NM_015925.6) | Missense Mutation (SNP) | VAF 112/672 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1201285752; called by muse, varscan2
- MAGEA12 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 108/310 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.764); catalogued as COSV63294327; called by muse, mutect2, varscan2
- MAPK15 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 123/676 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1554619751; called by muse, mutect2, varscan2
- MAPKBP1 | c.4057C>T p.P1353S (on ENST00000456763 / NM_001128608.2; = p.P1347S on NM_014994.3) | Missense Mutation (SNP) | VAF 105/586 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs770295928; called by muse, mutect2, varscan2
- MBD5 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV68698081; called by muse, mutect2, varscan2
- MEGF9 | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 108/410 reads (26%) | catalogued as COSV64237246; called by muse, mutect2, varscan2
- METTL3 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 53/314 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52970552; called by muse, mutect2, varscan2
- MMP26 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 111/627 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs368459718, COSV56173504; called by muse, mutect2, varscan2
- MUC15 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 73/512 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs1479949276; called by muse, mutect2, varscan2
- MUC16 | c.15346G>A p.E5116K | Missense Mutation (SNP) | VAF 64/342 reads (19%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.041); catalogued as rs866107833, COSV67449897; called by muse, mutect2, varscan2
- MUC16 | c.15083G>A p.W5028* | Nonsense Mutation (SNP) | VAF 82/524 reads (16%) | catalogued as COSV67447329; called by muse, mutect2
- MYH6 | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 41/479 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs397516762, CM159425, COSV62453369; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCF2 | c.924G>A p.Q308= | Splice Region (SNP) | VAF 74/468 reads (16%) | catalogued as COSV62315730; called by muse, mutect2, varscan2
- NCOA6 | c.4469C>T p.S1490L | Missense Mutation (SNP) | VAF 77/446 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1288559140, COSV62861530; called by muse, mutect2, varscan2
- NFATC1 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 60/369 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as rs775236204, COSV53710441; called by muse, mutect2, varscan2
- NRIP2 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 82/474 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1185143719; called by muse, mutect2, varscan2
- NWD1 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 96/498 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs568405169, COSV60339667; called by muse, mutect2, varscan2
- OR2J3 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 81/561 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65848766; called by muse, mutect2, varscan2
- OR2M2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 64/366 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV62897957; called by muse, mutect2, varscan2
- OR2M5 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 93/578 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs749039050, COSV63545850; called by muse, mutect2, varscan2
- OR2T34 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 102/822 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV60899992, COSV60900064; called by muse, varscan2
- OR4A15 | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 84/469 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs780246685, COSV59035571, COSV59036057; called by muse, mutect2, varscan2
- OR4D5 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 113/532 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58309328, COSV58309927; called by muse, mutect2, varscan2
- OR51A7 | c.506G>C p.C169S | Missense Mutation (SNP) | VAF 77/416 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV63787964, COSV63788395, COSV63788839; called by muse, mutect2, varscan2
- OTOGL | c.5431G>A p.E1811K (on ENST00000547103; = p.E1802K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV54024787; called by muse, mutect2, varscan2
- OTOGL | c.5797G>A p.E1933K (on ENST00000547103; = p.E1924K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756958173, COSV54017465; called by muse, mutect2, varscan2
- PCDHA9 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 99/644 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.521); catalogued as rs1306922979; called by muse, mutect2, varscan2
- PCDHB2 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 85/481 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.044); catalogued as rs781990058, COSV52036621; called by muse, mutect2, varscan2
- PCLO | c.10625G>A p.R3542Q | Missense Mutation (SNP) | VAF 85/507 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs1467096191, COSV100426546; called by muse, mutect2, varscan2
- PGLYRP4 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 251/701 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV100668264; called by muse, mutect2, varscan2
- PIK3C2G | c.3836C>T p.S1279L (on ENST00000676171; = p.S1238L on NM_004570.5) | Missense Mutation (SNP) | VAF 88/407 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs935135637, COSV56800636, COSV56812711; called by muse, mutect2, varscan2
- PKM | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 57/429 reads (13%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.566); catalogued as rs759479994; called by muse, mutect2, varscan2
- PLCH1 | c.84G>A p.M28I (on ENST00000340059 / NM_001130960.2; = p.M40I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/469 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100397114, COSV100398559; called by muse, mutect2, varscan2
- POLD2 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 79/566 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs138987928; called by muse, mutect2, varscan2
- PTPRC | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 104/555 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs369888892; called by muse, mutect2, varscan2
- RBM27 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 61/396 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1318366493; called by muse, mutect2, varscan2
- ROBO2 | c.2162G>A p.G721E | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165056, COSV59894479; called by muse, mutect2, varscan2
- RYR2 | c.9466G>A p.G3156R | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749825473; called by muse, mutect2, varscan2
- SCG3 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as rs549211117; called by muse, mutect2, varscan2
- SERPINB3 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV52192146, COSV52194622; called by muse, mutect2, varscan2
- SLC12A7 | c.2126C>T p.P709L | Missense Mutation (SNP) | VAF 148/784 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs1209507505; called by muse, mutect2, varscan2
- SLC13A1 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 77/376 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs773673398, COSV52009439; called by muse, mutect2, varscan2
- SLC1A6 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 103/585 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs773195255, COSV55670449; called by muse, mutect2, varscan2
- SLC26A5 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 92/524 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.261); catalogued as COSV59705018; called by muse, mutect2, varscan2
- SLC2A4RG | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 91/544 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs1289136159; called by muse, varscan2
- SLC8A1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 117/450 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.021); catalogued as COSV60478928; called by muse, mutect2, varscan2
- SLC8A3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 72/410 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.626); catalogued as COSV63521966, COSV63527980; called by muse, mutect2, varscan2
- SLCO2B1 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 83/498 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414989882; called by muse, mutect2, varscan2
- SLCO6A1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 60/418 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.219); catalogued as COSV65808866; called by muse, mutect2, varscan2
- SMIM10L2B | c.39_41dup p.A15dup | In Frame Ins (INS) | VAF 74/240 reads (31%) | catalogued as rs1474966068; called by mutect2, varscan2
- SNRPN | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 113/660 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV57600553; called by muse, mutect2, varscan2
- SPINT3 | c.262T>C p.F88L | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs1260554754; called by muse, mutect2, varscan2
- SPRR1A | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 138/1039 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs774846454, COSV61081288; called by muse, mutect2, varscan2
- SPTA1 | c.1395G>A p.W465* | Nonsense Mutation (SNP) | VAF 284/722 reads (39%) | catalogued as rs775455995, COSV63757006; called by muse, mutect2, varscan2
- STAB1 | c.4313C>T p.S1438F | Missense Mutation (SNP) | VAF 147/743 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs778304310; called by muse, mutect2, varscan2
- STEAP4 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 97/532 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs376035088; called by muse, mutect2, varscan2
- SV2C | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 87/533 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.495); catalogued as rs367890274; called by muse, mutect2, varscan2
- SYT10 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 63/406 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs752724042, COSV57342797; called by muse, mutect2, varscan2
- TBC1D8B | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 97/292 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778624354; called by muse, mutect2, varscan2
- TBXA2R | c.665T>A p.L222Q | Missense Mutation (SNP) | VAF 114/672 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64343583; called by muse, mutect2, varscan2
- TET1 | c.3035C>T p.S1012L | Missense Mutation (SNP) | VAF 59/318 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs1275579597, COSV65382491; called by muse, mutect2, varscan2
- TGM6 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 84/517 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.2); catalogued as rs546728628; called by muse, mutect2, varscan2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 108/540 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by muse, varscan2
- TMEM207 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 70/444 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs375773945; called by muse, mutect2, varscan2
- TMEM35A | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 127/333 reads (38%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV54503173; called by muse, mutect2, varscan2
- TMEM45B | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 83/500 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs1356483956, COSV55655069; called by muse, mutect2, varscan2
- TNR | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 63/319 reads (20%) | catalogued as rs776846663, COSV54867827; called by muse, mutect2, varscan2
- TRIO | c.6697C>T p.P2233S | Missense Mutation (SNP) | VAF 85/470 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs61748186, COSV59990762; called by muse, mutect2, varscan2
- TRPM6 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV62503016; called by muse, mutect2, varscan2
- TTN | c.55700T>C p.I18567T (on ENST00000591111; = p.I11143T on NM_003319.4) | Missense Mutation (SNP) | VAF 96/417 reads (23%) | PolyPhen probably damaging (0.996); catalogued as rs752768925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBQLN3 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 85/475 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.083); catalogued as COSV61164191; called by muse, mutect2, varscan2
- UGT8 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 63/389 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60417704; called by muse, mutect2, varscan2
- URB1 | c.3428C>T p.S1143F | Missense Mutation (SNP) | VAF 109/556 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.131); catalogued as rs773260000; called by muse, mutect2, varscan2
- UTY | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as rs779820442; called by muse, mutect2, varscan2
- WASHC4 | c.3254G>A p.R1085K | Missense Mutation (SNP) | VAF 93/457 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.023); catalogued as COSV59892297; called by muse, mutect2, varscan2
- XIRP2 | c.1966G>A p.E656K (on ENST00000628543; = p.E831K on NM_152381.6) | Missense Mutation (SNP) | VAF 91/369 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV54679776, COSV99748346; called by muse, mutect2, varscan2
- YLPM1 | c.5974C>T p.R1992C | Missense Mutation (SNP) | VAF 61/334 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs773988090; called by muse, mutect2, varscan2
- ZBED9 | c.2776G>A p.D926N | Missense Mutation (SNP) | VAF 102/611 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs767442848; called by muse, mutect2, varscan2
- ZFHX4 | c.5167C>T p.P1723S | Missense Mutation (SNP) | VAF 105/581 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs866599341, COSV50512080, COSV51476340; called by muse, mutect2, varscan2
- ZFHX4 | c.8207C>T p.P2736L | Missense Mutation (SNP) | VAF 96/470 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV51482294; called by muse, mutect2, varscan2
- ZFPM2 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 81/494 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.34); catalogued as rs1454243628; called by muse, mutect2, varscan2
- ZMAT4 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 78/502 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.212); catalogued as COSV52690451; called by muse, mutect2, varscan2
- ZNF205 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 122/676 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as rs1446949703; called by muse, mutect2, varscan2
- ZNF558 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 59/411 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs782004724; called by muse, mutect2, varscan2
- ADCY5 | c.1365G>A p.M455I | Missense Mutation (SNP) | VAF 73/433 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADGRV1 | c.14035G>A p.E4679K | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADPRHL1 | c.2011G>A p.G671R | Missense Mutation (SNP) | VAF 88/586 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AGAP6 | c.1241C>T p.A414V (on ENST00000374056 / NM_001365867.1; = p.A437V on NM_001077665.2) | Missense Mutation (SNP) | VAF 99/664 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AL713999.2 | c.535T>C p.F179L | Missense Mutation (SNP) | VAF 82/535 reads (15%) | called by muse, mutect2, varscan2
- ANAPC4 | c.1630del p.I544Lfs*5 | Frame Shift Del (DEL) | VAF 29/164 reads (18%) | called by mutect2, pindel, varscan2
- ANKRD30B | c.2273G>A p.G758E | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ANXA13 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 55/348 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APOA4 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 144/746 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- APOBR | c.824G>A p.W275* | Nonsense Mutation (SNP) | VAF 140/788 reads (18%) | called by muse, mutect2, varscan2
- ARSF | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ATL1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ATXN7 | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 116/624 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- BCO1 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 89/433 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BPIFB1 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 93/509 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- BRDT | c.1762A>T p.M588L | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C10orf71 | c.3980C>T p.A1327V | Missense Mutation (SNP) | VAF 112/504 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C11orf65 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 103/493 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- C18orf63 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- C1orf43 | c.358G>A p.E120K (on ENST00000368521 / NM_001297718.2; = p.E86K on NM_015449.4) | Missense Mutation (SNP) | VAF 202/503 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- C6 | c.2279C>T p.T760I | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CCDC158 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 84/489 reads (17%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CCDC168 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CCDC73 | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CD2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 92/492 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CDH9 | c.656C>A p.T219N | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CENPE | c.770A>T p.N257I | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CFAP300 | c.555T>G p.D185E | Missense Mutation (SNP) | VAF 68/452 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHD6 | c.2768T>C p.L923P | Missense Mutation (SNP) | VAF 80/472 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRM1 | c.449G>T p.W150L | Missense Mutation (SNP) | VAF 137/633 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CLCNKA | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CLEC3A | c.535T>C p.F179L (on ENST00000651443; = p.F170L on NM_005752.6) | Missense Mutation (SNP) | VAF 107/504 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLIC6 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 146/863 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLMN | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 78/521 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- CNTNAP4 | c.2504G>A p.G835E | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP5 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 77/350 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- COL16A1 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 75/468 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREBZF | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 66/525 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.378); called by mutect2, varscan2
- CSNK2B | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 90/692 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CTC1 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 93/385 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CYFIP1 | c.2728G>A p.G910R | Missense Mutation (SNP) | VAF 78/429 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CYP1A1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 91/504 reads (18%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DNAH8 | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 141/534 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, varscan2
- DRC7 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 73/390 reads (19%) | called by muse, mutect2, varscan2
- DSCAM | c.5794C>T p.Q1932* | Nonsense Mutation (SNP) | VAF 107/519 reads (21%) | called by muse, mutect2, varscan2
- EPHA4 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- EPHA6 | c.2574G>A p.R858= (on ENST00000389672 / NM_001080448.3; = p.R250= on NM_173655.4) | Splice Region (SNP) | VAF 51/295 reads (17%) | called by muse, mutect2, varscan2
- ESPN | c.2630T>G p.I877S | Missense Mutation (SNP) | VAF 71/423 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ETV6 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 105/643 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- EVC2 | c.1654G>A p.G552R | Missense Mutation (SNP) | VAF 73/412 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM13C | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 107/445 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT1 | c.11899C>T p.P3967S | Missense Mutation (SNP) | VAF 85/462 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FBN1 | c.5210C>T p.P1737L | Missense Mutation (SNP) | VAF 65/413 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCHO1 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 98/610 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- FMN1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 76/477 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.84); called by muse, mutect2
- FNIP2 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 70/409 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- FOXL2 | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 82/488 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GALNT9 | c.848A>G p.E283G | Missense Mutation (SNP) | VAF 98/552 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GALNTL5 | c.148A>G p.K50E | Missense Mutation (SNP) | VAF 82/445 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GALNTL5 | c.260A>C p.N87T | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.421); called by mutect2, varscan2
- GBP1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GDF10 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 91/460 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GEMIN5 | c.3754C>T p.P1252S | Missense Mutation (SNP) | VAF 65/322 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR63 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 64/397 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- HASPIN | c.2320A>G p.I774V | Missense Mutation (SNP) | VAF 93/465 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- HELQ | c.1265T>C p.F422S | Missense Mutation (SNP) | VAF 88/426 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- HLA-DPA1 | c.25C>T p.H9Y | Missense Mutation (SNP) | VAF 204/658 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- IFT140 | c.4185C>T p.A1395= | Splice Region (SNP) | VAF 42/386 reads (11%) | called by muse, mutect2, varscan2
- IFT140 | c.4184C>T p.A1395V | Missense Mutation (SNP) | VAF 39/382 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- IGHV3-33 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 84/926 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- IGKV6D-21 | c.223T>G p.S75A | Missense Mutation (SNP) | VAF 85/466 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- ITGAL | c.3305T>G p.L1102R | Missense Mutation (SNP) | VAF 98/528 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by mutect2, varscan2
- ITGB3 | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 76/497 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ITM2C | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 73/341 reads (21%) | called by muse, mutect2, varscan2
- JAML | c.337A>G p.T113A (on ENST00000356289 / NM_001098526.2; = p.T103A on NM_153206.3) | Missense Mutation (SNP) | VAF 93/563 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- KDM1A | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM1A | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0232 | c.860C>G p.S287W | Missense Mutation (SNP) | VAF 95/471 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF21A | c.2389C>T p.Q797* (on ENST00000361418 / NM_001378440.1; = p.Q784* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/292 reads (12%) | called by muse, mutect2, varscan2
- LGI2 | c.344T>A p.F115Y | Missense Mutation (SNP) | VAF 65/373 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIPE | c.1512T>A p.S504R | Missense Mutation (SNP) | VAF 65/427 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- LMAN1 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- LMBRD1 | c.1067C>T p.S356L (on ENST00000649011; = p.S334L on NM_018368.4) | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LMF1 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 109/713 reads (15%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LRRC46 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 129/732 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRIQ1 | c.3164C>T p.S1055L | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MC2R | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 57/406 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- MRC1 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 112/499 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.42523C>T p.Q14175* | Nonsense Mutation (SNP) | VAF 62/498 reads (12%) | called by muse, mutect2, varscan2
- MUC16 | c.20276C>T p.S6759F | Missense Mutation (SNP) | VAF 91/511 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.452); called by muse, varscan2
- MUC16 | c.13969G>A p.D4657N | Missense Mutation (SNP) | VAF 112/560 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MUC16 | c.6603G>A p.W2201* | Nonsense Mutation (SNP) | VAF 59/407 reads (14%) | called by muse, mutect2, varscan2
- MYO3A | c.3324G>A p.M1108I | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAALADL1 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 68/432 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAT10 | c.2941C>T p.P981S | Missense Mutation (SNP) | VAF 56/343 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBPF12 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 49/466 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- NCF2 | c.924+1G>A p.X308_splice | Splice Site (SNP) | VAF 73/467 reads (16%) | called by muse, mutect2, varscan2
- NEK11 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 58/339 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- NES | c.4744G>A p.E1582K | Missense Mutation (SNP) | VAF 100/835 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- NTN3 | c.1661T>C p.V554A | Missense Mutation (SNP) | VAF 106/551 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- NUP98 | c.3101C>T p.S1034L (on ENST00000359171 / NM_001365126.1; = p.S1017L on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/370 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- OTOG | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OTOG | c.5719G>A p.A1907T | Missense Mutation (SNP) | VAF 89/517 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- OTOP1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PARP4 | c.4387C>T p.H1463Y | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA6 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 98/543 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHAC1 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 101/567 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCSK4 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 54/373 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PCYT1B | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 146/430 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDZRN4 | c.1902A>T p.K634N (on ENST00000402685 / NM_001164595.2; = p.K376N on NM_013377.4) | Missense Mutation (SNP) | VAF 79/362 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PGA5 | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 111/535 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- PHF14 | c.2297C>A p.T766N | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- PIK3C2A | c.4456C>T p.P1486S | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PILRB | c.-217-6C>T | Splice Region (SNP) | VAF 72/465 reads (15%) | called by muse, mutect2, varscan2
- PLCB4 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- POLQ | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 61/389 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- POSTN | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- POTEG | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 56/685 reads (8%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POU1F1 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 60/375 reads (16%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- POU2AF1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 80/546 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POU2F3 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRB4 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 133/706 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- PROSER1 | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 94/520 reads (18%) | called by muse, mutect2, varscan2
- PROX1 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 98/525 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PTCHD1 | c.743A>T p.K248I | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PTK7 | c.3101C>T p.S1034F | Missense Mutation (SNP) | VAF 73/635 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- PTPRB | c.1955A>G p.N652S | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RAP1GAP2 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 74/405 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- RASAL1 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 124/701 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASEL | c.944C>A p.S315Y | Missense Mutation (SNP) | VAF 80/454 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF150 | c.1224T>G p.S408R | Missense Mutation (SNP) | VAF 50/363 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- RNF17 | c.4348G>A p.G1450R | Missense Mutation (SNP) | VAF 67/489 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- ROS1 | c.5568G>A p.W1856* | Nonsense Mutation (SNP) | VAF 41/172 reads (24%) | called by muse, mutect2, varscan2
- RP1 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 69/346 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- RUVBL1 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 104/480 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SART1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 82/574 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- SCNN1G | c.1725G>A p.W575* | Nonsense Mutation (SNP) | VAF 109/601 reads (18%) | called by muse, mutect2, varscan2
- SCPEP1 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 94/431 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEC31B | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 86/499 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SF1 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 60/440 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SFMBT2 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC11A1 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 79/383 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SLC17A8 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 79/470 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC26A2 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 78/456 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SLC2A11 | c.1054G>A p.G352R (on ENST00000345044 / NM_001024938.4; = p.G359R on NM_030807.5) | Missense Mutation (SNP) | VAF 151/643 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SLC39A4 | c.551C>T p.A184V (on ENST00000301305 / NM_001374839.1; = p.A159V on NM_017767.3) | Missense Mutation (SNP) | VAF 152/818 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SP4 | c.2215C>T p.L739F | Missense Mutation (SNP) | VAF 80/461 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- SPATA3 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 116/530 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SPATA31A1 | c.3676G>A p.A1226T | Missense Mutation (SNP) | VAF 20/694 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.114); called by muse, mutect2
- SYNE3 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 45/305 reads (15%) | called by muse, mutect2, varscan2
- TACC2 | c.7045C>T p.P2349S (on ENST00000334433; = p.P427S on NM_006997.4) | Missense Mutation (SNP) | VAF 87/458 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TACC2 | c.7046C>T p.P2349L (on ENST00000334433; = p.P427L on NM_006997.4) | Missense Mutation (SNP) | VAF 88/461 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TASOR | c.772A>T p.K258* | Nonsense Mutation (SNP) | VAF 63/379 reads (17%) | called by muse, mutect2, varscan2
- TBX21 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- TDRD1 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEX50 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 67/404 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TKTL2 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 88/443 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TLCD2 | c.403T>A p.S135T | Missense Mutation (SNP) | VAF 144/530 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TMEM176B | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TMEM185B | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 115/525 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM63A | c.906_907insGCCAGCGGACCCTCATCAACCTTAAG p.P303Afs*34 | Frame Shift Ins (INS) | VAF 80/450 reads (18%) | called by mutect2, varscan2
- TMPRSS11B | c.1232_1239del p.T411Nfs*14 | Frame Shift Del (DEL) | VAF 36/254 reads (14%) | called by mutect2, pindel, varscan2
- TRANK1 | c.634A>C p.I212L | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- TRBV4-2 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 65/443 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- TRIM28 | c.1001C>T p.T334I | Missense Mutation (SNP) | VAF 85/668 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRPC7 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 113/586 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- TRPM6 | c.2590A>T p.M864L | Missense Mutation (SNP) | VAF 81/354 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TSC1 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 137/605 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTLL1 | c.1046A>T p.N349I | Missense Mutation (SNP) | VAF 126/557 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- TTLL10 | c.499G>A p.A167T (on ENST00000379289 / NM_001130045.2; = p.A94T on NM_153254.3) | Missense Mutation (SNP) | VAF 71/419 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- UGT2B4 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 43/363 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT3A2 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 94/543 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- WASHC2C | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 101/444 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- WDR27 | c.880A>T p.K294* | Nonsense Mutation (SNP) | VAF 50/343 reads (15%) | called by muse, mutect2
- WDR6 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 120/730 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- WDR72 | c.2972C>T p.A991V | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WIF1 | c.202C>G p.H68D | Missense Mutation (SNP) | VAF 59/415 reads (14%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WWC2 | c.3325C>T p.P1109S | Missense Mutation (SNP) | VAF 84/447 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZAN | c.7585C>T p.L2529F | Missense Mutation (SNP) | VAF 105/585 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB32 | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZHX2 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 75/456 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF185 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ZNF879 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 71/431 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZSCAN9 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 52/426 reads (12%) | called by muse, mutect2, varscan2
- ABCC12 | c.3273G>A p.R1091= | Silent (SNP) | VAF 61/318 reads (19%) | catalogued as rs902255107; called by muse, mutect2, varscan2
- ABCC5 | c.762C>T p.I254= | Silent (SNP) | VAF 90/530 reads (17%) | catalogued as rs766500883, COSV55592910; called by muse, mutect2, varscan2
- ACE | c.1470C>T p.F490= | Silent (SNP) | VAF 82/424 reads (19%) | catalogued as rs775141617, COSV52007044; called by muse, mutect2, varscan2
- ACSS3 | c.954C>T p.V318= | Silent (SNP) | VAF 49/346 reads (14%) | called by muse, mutect2, varscan2
- ACTR2 | c.471A>T p.V157= | Silent (SNP) | VAF 55/289 reads (19%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.3183G>A p.R1061= | Silent (SNP) | VAF 99/566 reads (17%) | called by muse, mutect2, varscan2
- ADCY9 | c.765T>G p.L255= | Silent (SNP) | VAF 96/555 reads (17%) | called by mutect2, varscan2
- AJUBA | c.894C>T p.R298= | Silent (SNP) | VAF 139/790 reads (18%) | catalogued as rs1019060030; called by muse, mutect2, varscan2
- AKAP9 | c.1428G>A p.R476= | Silent (SNP) | VAF 48/275 reads (17%) | called by muse, mutect2, varscan2
- ALPK2 | c.2097G>A p.K699= | Silent (SNP) | VAF 78/528 reads (15%) | catalogued as rs747160197; called by muse, mutect2, varscan2
- AMOTL1 | c.1242C>T p.A414= | Silent (SNP) | VAF 158/761 reads (21%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.1284A>T p.G428= | Silent (SNP) | VAF 59/383 reads (15%) | called by muse, mutect2, varscan2
- ASAP1 | c.1902G>A p.T634= | Silent (SNP) | VAF 62/362 reads (17%) | catalogued as rs753375926, COSV63054255; called by muse, mutect2, varscan2
- ATL1 | c.483C>T p.A161= | Silent (SNP) | VAF 52/343 reads (15%) | catalogued as rs370173293; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP13A4 | c.2925G>A p.V975= | Silent (SNP) | VAF 93/525 reads (18%) | catalogued as COSV61321496; called by muse, mutect2, varscan2
- ATP2B2 | c.2379C>T p.I793= (on ENST00000352432; = p.I759= on NM_001683.5) | Silent (SNP) | VAF 51/376 reads (14%) | catalogued as rs770333626, COSV59503255; called by muse, mutect2, varscan2
- ATP6AP1 | c.900C>T p.S300= | Silent (SNP) | VAF 91/270 reads (34%) | catalogued as rs1337979463; called by muse, mutect2, varscan2
- C6 | c.2280C>T p.T760= | Silent (SNP) | VAF 56/305 reads (18%) | called by muse, mutect2, varscan2
- CABLES1 | c.960G>A p.K320= (on ENST00000256925 / NM_001100619.2; = p.K55= on NM_138375.2) | Silent (SNP) | VAF 53/318 reads (17%) | called by muse, mutect2, varscan2
- CACNA1D | c.6339C>T p.P2113= (on ENST00000350061 / NM_001128840.3; = p.P2133= on NM_000720.4) | Silent (SNP) | VAF 101/604 reads (17%) | catalogued as COSV55444322; called by muse, mutect2, varscan2
- CACNA1E | c.3066G>A p.T1022= | Silent (SNP) | VAF 102/634 reads (16%) | catalogued as rs373164787; called by muse, mutect2, varscan2
- CACNA1H | c.3225C>T p.P1075= | Silent (SNP) | VAF 101/582 reads (17%) | catalogued as rs1040791509, COSV61992973; called by muse, mutect2, varscan2
- CACNA2D2 | c.813C>T p.I271= | Silent (SNP) | VAF 102/558 reads (18%) | called by muse, mutect2, varscan2
- CALD1 | c.1653C>T p.F551= (on ENST00000361675 / NM_033138.4; = p.F296= on NM_004342.7) | Silent (SNP) | VAF 103/609 reads (17%) | catalogued as rs757030162, COSV62645894; called by muse, mutect2, varscan2
- CATSPER1 | c.735G>A p.E245= | Silent (SNP) | VAF 96/645 reads (15%) | called by muse, mutect2, varscan2
- CCDC146 | c.2838G>A p.R946= | Silent (SNP) | VAF 74/333 reads (22%) | called by muse, mutect2, varscan2
- CCDC178 | c.1590C>T p.F530= | Silent (SNP) | VAF 55/229 reads (24%) | called by muse, mutect2, varscan2
- CCKAR | c.300C>T p.I100= | Silent (SNP) | VAF 111/538 reads (21%) | catalogued as COSV99810384; called by muse, mutect2, varscan2
- CEACAM5 | c.1755C>T p.V585= | Silent (SNP) | VAF 46/254 reads (18%) | catalogued as rs781969504; called by muse, mutect2, varscan2
- CFH | c.3030G>A p.A1010= | Silent (SNP) | VAF 93/495 reads (19%) | catalogued as rs1290292015; called by muse, mutect2, varscan2
- CHAT | c.1356G>A p.Q452= | Silent (SNP) | VAF 81/339 reads (24%) | catalogued as rs1288648346; called by muse, mutect2, varscan2
- CHD6 | c.2767C>T p.L923= | Silent (SNP) | VAF 80/474 reads (17%) | called by muse, mutect2, varscan2
- CKAP4 | c.1272G>A p.Q424= | Silent (SNP) | VAF 85/616 reads (14%) | called by muse, mutect2, varscan2
- CLEC5A | c.543G>A p.R181= | Silent (SNP) | VAF 54/351 reads (15%) | catalogued as COSV69397300; called by muse, mutect2, varscan2
- CLMN | c.1677C>T p.I559= | Silent (SNP) | VAF 71/385 reads (18%) | catalogued as rs865887178; called by muse, mutect2, varscan2
- CLTC | c.1968T>C p.G656= | Silent (SNP) | VAF 51/291 reads (18%) | called by muse, mutect2, varscan2
- COL16A1 | c.1053G>A p.K351= | Silent (SNP) | VAF 75/472 reads (16%) | catalogued as COSV99594179; called by muse, mutect2, varscan2
- CR1 | c.2754C>T p.I918= | Silent (SNP) | VAF 127/776 reads (16%) | called by muse, mutect2, varscan2
- CXADR | c.309A>G p.A103= | Silent (SNP) | VAF 80/419 reads (19%) | called by muse, mutect2, varscan2
- DDX60L | c.4335C>T p.F1445= | Silent (SNP) | VAF 69/405 reads (17%) | called by muse, mutect2, varscan2
- DEFB4A | c.6G>A p.R2= | Silent (SNP) | VAF 76/1240 reads (6%) | catalogued as rs775486089; called by muse, mutect2
- DNAH2 | c.6384G>A p.G2128= | Silent (SNP) | VAF 75/367 reads (20%) | called by muse, mutect2, varscan2
- DOCK3 | c.1791G>A p.Q597= | Silent (SNP) | VAF 51/388 reads (13%) | catalogued as COSV56541445; called by muse, mutect2, varscan2
- DPP6 | c.1443C>T p.T481= (on ENST00000377770 / NM_001364500.2; = p.T419= on NM_001936.5) | Silent (SNP) | VAF 86/494 reads (17%) | catalogued as rs755015968, COSV59606169; called by muse, mutect2, varscan2
- EPHA10 | c.690C>T p.F230= | Silent (SNP) | VAF 127/683 reads (19%) | catalogued as rs879055562; called by muse, mutect2, varscan2
- EPHB4 | c.2101C>T p.L701= | Silent (SNP) | VAF 66/328 reads (20%) | called by muse, mutect2, varscan2
- ERICH3 | c.1059C>T p.F353= | Silent (SNP) | VAF 85/442 reads (19%) | catalogued as rs769875646, COSV58607407; called by mutect2, varscan2
- FGFR2 | c.2465G>A p.*822= | Silent (SNP) | VAF 55/265 reads (21%) | called by muse, mutect2, varscan2
- FLNC | c.6525A>C p.T2175= | Silent (SNP) | VAF 78/488 reads (16%) | called by muse, varscan2
- FLT4 | c.393C>T p.F131= | Silent (SNP) | VAF 71/365 reads (19%) | catalogued as rs267600585, COSV56117608, COSV56119531; called by muse, mutect2, varscan2
- FMN2 | c.5091G>A p.Q1697= | Silent (SNP) | VAF 52/325 reads (16%) | called by muse, mutect2, varscan2
- FNDC3A | c.69C>T p.A23= | Silent (SNP) | VAF 54/284 reads (19%) | called by muse, mutect2, varscan2
- GATA3 | c.393C>T p.S131= | Silent (SNP) | VAF 149/690 reads (22%) | catalogued as rs959805514, COSV60516886; called by muse, mutect2, varscan2
- GK3P | c.1449G>A p.T483= | Silent (SNP) | VAF 75/545 reads (14%) | catalogued as rs771243890; called by muse, mutect2, varscan2
- GLP2R | c.1140A>G p.K380= | Silent (SNP) | VAF 47/252 reads (19%) | called by muse, mutect2, varscan2
- GPR63 | c.654C>T p.P218= | Silent (SNP) | VAF 64/394 reads (16%) | catalogued as rs370572252; called by muse, mutect2, varscan2
- GRIN2B | c.369C>T p.I123= | Silent (SNP) | VAF 74/457 reads (16%) | catalogued as COSV74204858; called by muse, mutect2, varscan2
- GRM4 | c.1317C>T p.D439= | Silent (SNP) | VAF 216/669 reads (32%) | called by muse, mutect2, varscan2
- GTF2IRD2B | c.2257C>T p.L753= | Silent (SNP) | VAF 39/370 reads (11%) | called by muse, mutect2, varscan2
- GUCD1 | c.408C>T p.I136= | Silent (SNP) | VAF 58/341 reads (17%) | called by muse, mutect2, varscan2
- HIF1A | c.846G>A p.L282= | Silent (SNP) | VAF 57/298 reads (19%) | called by muse, mutect2, varscan2
- HIF3A | c.153G>A p.L51= (on ENST00000377670 / NM_152795.4; = p.W31* on NM_022462.4) | Silent (SNP) | VAF 96/593 reads (16%) | called by muse, mutect2, varscan2
- HRC | c.1437G>A p.K479= | Silent (SNP) | VAF 119/727 reads (16%) | called by muse, mutect2, varscan2
- ICE1 | c.5388C>T p.F1796= | Silent (SNP) | VAF 85/564 reads (15%) | catalogued as rs1388500863; called by muse, mutect2, varscan2
- IGSF21 | c.957C>T p.F319= | Silent (SNP) | VAF 125/588 reads (21%) | catalogued as rs1432513502; called by muse, mutect2, varscan2
- IL18R1 | c.966C>T p.I322= | Silent (SNP) | VAF 61/333 reads (18%) | catalogued as COSV52127289; called by muse, mutect2, varscan2
- IL3RA | c.9C>T p.L3= | Silent (SNP) | VAF 82/550 reads (15%) | catalogued as rs768766086, COSV100452249; called by muse, mutect2, varscan2
- INPP5D | c.1260G>A p.K420= (on ENST00000445964 / NM_001017915.3; = p.K419= on NM_005541.5) | Silent (SNP) | VAF 71/345 reads (21%) | called by muse, mutect2, varscan2
- ITGA7 | c.1359G>A p.G453= (on ENST00000555728; = p.G409= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/351 reads (24%) | called by muse, mutect2, varscan2
- ITM2C | c.594C>T p.I198= | Silent (SNP) | VAF 73/338 reads (22%) | called by muse, mutect2, varscan2
- KCNB1 | c.2400C>T p.S800= | Silent (SNP) | VAF 120/667 reads (18%) | catalogued as rs950272613; called by muse, mutect2, varscan2
- KDM2B | c.2427C>T p.P809= | Silent (SNP) | VAF 100/488 reads (20%) | catalogued as rs1313197001; called by muse, mutect2
- KLHL29 | c.1065G>A p.K355= | Silent (SNP) | VAF 54/275 reads (20%) | called by muse, mutect2, varscan2
- KRT6A | c.420C>T p.V140= | Silent (SNP) | VAF 106/604 reads (18%) | called by muse, mutect2, varscan2
- KSR1 | c.1170C>A p.A390= (on ENST00000644974 / NM_001367810.1; = p.A253= on NM_014238.2) | Silent (SNP) | VAF 69/397 reads (17%) | called by muse, mutect2, varscan2
- KSR2 | c.801C>T p.I267= | Silent (SNP) | VAF 108/776 reads (14%) | catalogued as rs778723428, COSV60367834; called by muse, mutect2, varscan2
- LGMN | c.48T>C p.G16= | Silent (SNP) | VAF 81/450 reads (18%) | called by muse, mutect2, varscan2
- LGR5 | c.1599G>A p.L533= | Silent (SNP) | VAF 46/331 reads (14%) | called by muse, mutect2, varscan2
- LILRB3 | c.1854G>A p.K618= (on ENST00000346401; = p.K606= on NM_006864.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 125/786 reads (16%) | catalogued as rs1448066228; called by muse, mutect2, varscan2
- LRRK1 | c.2352C>T p.S784= | Silent (SNP) | VAF 110/652 reads (17%) | called by muse, mutect2
- LYSMD1 | c.471C>T p.F157= | Silent (SNP) | VAF 67/670 reads (10%) | catalogued as COSV64420137; called by muse, mutect2, varscan2
- MAST4 | c.1716G>A p.T572= (on ENST00000403625 / NM_001164664.2; = p.T383= on NM_015183.3) | Silent (SNP) | VAF 64/376 reads (17%) | catalogued as rs764436771; called by muse, mutect2, varscan2
- MEX3C | c.861C>T p.A287= | Silent (SNP) | VAF 81/495 reads (16%) | catalogued as rs559716751; called by muse, mutect2, varscan2
- MORC3 | c.1401A>G p.K467= | Silent (SNP) | VAF 58/300 reads (19%) | called by muse, mutect2, varscan2
- MTMR14 | c.351C>T p.I117= | Silent (SNP) | VAF 97/474 reads (20%) | called by muse, mutect2, varscan2
- MUC15 | c.306C>T p.P102= | Silent (SNP) | VAF 75/513 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.20208C>T p.I6736= | Silent (SNP) | VAF 104/524 reads (20%) | catalogued as COSV67456101; called by muse, varscan2
- N4BP3 | c.384C>T p.F128= | Silent (SNP) | VAF 79/483 reads (16%) | called by muse, mutect2, varscan2
- NEB | c.6936C>T p.Y2312= | Silent (SNP) | VAF 52/252 reads (21%) | called by muse, mutect2, varscan2
- NES | c.2529A>G p.P843= | Silent (SNP) | VAF 293/815 reads (36%) | catalogued as rs1282999267; called by muse, mutect2, varscan2
- NFATC1 | c.1179C>T p.P393= | Silent (SNP) | VAF 60/362 reads (17%) | called by muse, mutect2, varscan2
- NIM1K | c.795G>A p.V265= | Silent (SNP) | VAF 105/528 reads (20%) | catalogued as rs368925912; called by muse, mutect2, varscan2
- NLRP10 | c.246C>T p.N82= | Silent (SNP) | VAF 113/634 reads (18%) | called by muse, mutect2, varscan2
- NLRP9 | c.654C>T p.S218= | Silent (SNP) | VAF 85/466 reads (18%) | catalogued as COSV100243197, COSV60460681; called by muse, mutect2, varscan2
- NOL10 | c.1182C>T p.F394= | Silent (SNP) | VAF 73/320 reads (23%) | catalogued as rs774391004, COSV62038076; called by muse, mutect2, varscan2
- NOMO1 | c.264C>T p.F88= | Silent (SNP) | VAF 7/46 reads (15%) | called by mutect2, varscan2
- OPRK1 | c.1125G>A p.G375= | Silent (SNP) | VAF 48/226 reads (21%) | called by muse, mutect2, varscan2
- OR10J3 | c.138C>T p.I46= | Silent (SNP) | VAF 96/701 reads (14%) | catalogued as COSV59953920, COSV59955339; called by muse, mutect2, varscan2
- OR11G2 | c.594C>T p.I198= | Silent (SNP) | VAF 60/390 reads (15%) | catalogued as COSV62132282; called by muse, mutect2, varscan2
- OR11H12 | c.450C>T p.I150= | Silent (SNP) | VAF 76/2480 reads (3%) | catalogued as COSV73569136; called by muse, mutect2
- OR11L1 | c.819C>T p.I273= | Silent (SNP) | VAF 64/377 reads (17%) | catalogued as COSV100869410, COSV63313737; called by muse, mutect2, varscan2
- OR1S2 | c.162G>A p.G54= | Silent (SNP) | VAF 96/576 reads (17%) | catalogued as rs758172674; called by muse, mutect2, varscan2
- OR2B2 | c.342C>T p.L114= | Silent (SNP) | VAF 193/599 reads (32%) | called by muse, mutect2, varscan2
- OR2T34 | c.537C>T p.I179= | Silent (SNP) | VAF 71/661 reads (11%) | called by muse, varscan2
- OR4A47 | c.315C>T p.F105= | Silent (SNP) | VAF 54/446 reads (12%) | catalogued as rs369032935; called by muse, varscan2
- OR4K17 | c.666C>T p.L222= | Silent (SNP) | VAF 87/484 reads (18%) | catalogued as rs780616031, COSV59647539; called by muse, mutect2, varscan2
- OR4N2 | c.559C>T p.L187= | Silent (SNP) | VAF 93/876 reads (11%) | called by muse, mutect2, varscan2
- OR56A5 | c.222C>T p.I74= | Silent (SNP) | VAF 153/691 reads (22%) | catalogued as rs780832376, COSV60827506; called by muse, mutect2, varscan2
- OR56B4 | c.756C>T p.I252= | Silent (SNP) | VAF 88/567 reads (16%) | called by muse, mutect2, varscan2
- OR9H1P | c.81G>A p.L27= | Silent (SNP) | VAF 61/405 reads (15%) | called by muse, mutect2, varscan2
- OTOF | c.321C>T p.I107= | Silent (SNP) | VAF 71/325 reads (22%) | called by muse, mutect2, varscan2
- PAK5 | c.825G>A p.Q275= | Silent (SNP) | VAF 107/555 reads (19%) | called by muse, mutect2, varscan2
- PCDHB16 | c.1377C>T p.F459= | Silent (SNP) | VAF 107/646 reads (17%) | catalogued as rs782620895, COSV53358498; called by muse, mutect2, varscan2
- PGLYRP3 | c.435C>T p.I145= | Silent (SNP) | VAF 239/588 reads (41%) | called by muse, mutect2, varscan2
- PKM | c.1461C>T p.D487= | Silent (SNP) | VAF 58/435 reads (13%) | called by muse, mutect2, varscan2
- PKN2 | c.2388G>A p.V796= | Silent (SNP) | VAF 43/327 reads (13%) | catalogued as COSV65144061; called by muse, mutect2, varscan2
- PLA2G6 | c.1323C>T p.P441= | Silent (SNP) | VAF 84/439 reads (19%) | called by muse, mutect2, varscan2
- PLCE1 | c.108C>T p.I36= | Silent (SNP) | VAF 79/383 reads (21%) | catalogued as rs1196077053; called by muse, mutect2, varscan2
- PLCH1 | c.1146G>A p.V382= (on ENST00000340059 / NM_001130960.2; = p.V394= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/258 reads (14%) | catalogued as rs1179553041; called by muse, mutect2, varscan2
- POLD2 | c.141C>T p.S47= | Silent (SNP) | VAF 83/568 reads (15%) | called by muse, mutect2, varscan2
- PPP1R9B | c.690C>T p.L230= | Silent (SNP) | VAF 123/648 reads (19%) | called by muse, mutect2, varscan2
- PRDM1 | c.1239C>T p.F413= | Silent (SNP) | VAF 112/580 reads (19%) | catalogued as COSV64847204; called by muse, mutect2, varscan2
- PRDM6 | c.1002A>G p.E334= | Silent (SNP) | VAF 62/335 reads (19%) | called by muse, mutect2, varscan2
- PRDX5 | c.249G>A p.K83= | Silent (SNP) | VAF 105/629 reads (17%) | called by muse, mutect2, varscan2
- PRSS51 | c.285G>A p.V95= | Silent (SNP) | VAF 55/328 reads (17%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1017G>A p.L339= | Silent (SNP) | VAF 93/562 reads (17%) | catalogued as rs1484941539; called by muse, mutect2, varscan2
- RNF217 | c.1140C>T p.F380= (on ENST00000521654 / NM_001286398.2; = p.F88= on NM_152553.5) | Silent (SNP) | VAF 72/300 reads (24%) | catalogued as rs140177984; called by muse, mutect2, varscan2
- ROR2 | c.186G>A p.L62= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as rs1313898393, COSV65222777; called by muse, mutect2, varscan2
- RPL13A | c.246G>A p.R82= | Silent (SNP) | VAF 73/517 reads (14%) | catalogued as rs143541099; called by muse, mutect2, varscan2
- RPL28 | c.351G>A p.Q117= | Silent (SNP) | VAF 72/398 reads (18%) | called by muse, mutect2, varscan2
- RSPH3 | c.1185C>T p.I395= (on ENST00000252655; = p.I253= on NM_031924.8) | Silent (SNP) | VAF 62/407 reads (15%) | catalogued as rs1206690782, COSV51921924; called by muse, varscan2
- RTL1 | c.3456C>T p.L1152= | Silent (SNP) | VAF 117/586 reads (20%) | catalogued as rs1217033791; called by muse, mutect2, varscan2
- SARDH | c.2040G>A p.L680= | Silent (SNP) | VAF 77/374 reads (21%) | called by muse, mutect2, varscan2
- SBNO1 | c.39G>A p.L13= | Silent (SNP) | VAF 71/417 reads (17%) | called by muse, mutect2, varscan2
- SEPHS1 | c.1179A>G p.*393= | Silent (SNP) | VAF 59/247 reads (24%) | called by muse, mutect2, varscan2
- SH3BP2 | c.1371C>T p.V457= | Silent (SNP) | VAF 79/393 reads (20%) | called by muse, mutect2, varscan2
- SKP2 | c.1110C>T p.I370= | Silent (SNP) | VAF 83/432 reads (19%) | catalogued as rs761744015, COSV57043297; called by muse, mutect2, varscan2
- SLC12A6 | c.2388C>T p.I796= (on ENST00000354181 / NM_001365088.1; = p.I745= on NM_005135.2) | Silent (SNP) | VAF 83/471 reads (18%) | catalogued as rs771038983, COSV99273013; called by muse, mutect2, varscan2
- SLC2A4RG | c.432C>T p.P144= | Silent (SNP) | VAF 101/576 reads (18%) | catalogued as rs145320298; called by muse, mutect2, varscan2
- SLIT2 | c.3960C>T p.F1320= | Silent (SNP) | VAF 87/533 reads (16%) | catalogued as rs146274595; called by muse, mutect2, varscan2
- SNPH | c.294C>T p.D98= | Silent (SNP) | VAF 74/464 reads (16%) | called by muse, mutect2, varscan2
- SPHK2 | c.651C>T p.L217= | Silent (SNP) | VAF 62/336 reads (18%) | called by muse, varscan2
- SPINT1 | c.1212C>T p.I404= (on ENST00000344051 / NM_181642.3; = p.I388= on NM_003710.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/542 reads (17%) | catalogued as rs746313007; called by muse, mutect2, varscan2
- SPTLC3 | c.1254C>T p.I418= | Silent (SNP) | VAF 39/261 reads (15%) | called by muse, mutect2, varscan2
- STAT6 | c.2295G>A p.V765= | Silent (SNP) | VAF 90/494 reads (18%) | called by muse, mutect2, varscan2
- SUPT6H | c.1992C>T p.L664= | Silent (SNP) | VAF 82/505 reads (16%) | called by muse, mutect2, varscan2
- TBXA2R | c.664C>T p.L222= | Silent (SNP) | VAF 114/681 reads (17%) | catalogued as rs1184252700; called by muse, mutect2, varscan2
- TDRD12 | c.3981C>T p.D1327= | Silent (SNP) | VAF 58/423 reads (14%) | catalogued as rs1466858515; called by muse, mutect2, varscan2
- TGM2 | c.1554G>A p.G518= | Silent (SNP) | VAF 100/544 reads (18%) | called by muse, mutect2, varscan2
- TMEM184A | c.999G>A p.K333= | Silent (SNP) | VAF 60/340 reads (18%) | called by muse, mutect2, varscan2
- TMEM45B | c.471G>A p.G157= | Silent (SNP) | VAF 84/507 reads (17%) | called by muse, mutect2, varscan2
- TMPRSS4 | c.384C>T p.F128= | Silent (SNP) | VAF 83/446 reads (19%) | catalogued as rs752005139, COSV71109854; called by muse, mutect2, varscan2
- TRANK1 | c.993G>A p.R331= | Silent (SNP) | VAF 76/426 reads (18%) | called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.315G>A p.G105= | Silent (SNP) | VAF 73/330 reads (22%) | called by muse, mutect2, varscan2
- TXNDC12 | c.300C>G p.P100= | Silent (SNP) | VAF 45/372 reads (12%) | called by muse, mutect2, varscan2
- UBXN7 | c.813C>T p.P271= | Silent (SNP) | VAF 75/408 reads (18%) | catalogued as rs370907976; called by muse, mutect2, varscan2
- UGT1A7 | c.777G>A p.L259= | Silent (SNP) | VAF 71/326 reads (22%) | called by muse, mutect2, varscan2
- USH2A | c.14562C>T p.F4854= | Silent (SNP) | VAF 61/313 reads (19%) | catalogued as COSV56328419; called by muse, mutect2, varscan2
- UTP14A | c.678G>A p.E226= | Silent (SNP) | VAF 94/274 reads (34%) | catalogued as rs1490558122; called by muse, mutect2, varscan2
- VPS13D | c.10473C>T p.F3491= | Silent (SNP) | VAF 53/316 reads (17%) | catalogued as rs745931838; called by muse, mutect2, varscan2
- WDFY4 | c.6996C>T p.N2332= | Silent (SNP) | VAF 38/156 reads (24%) | called by muse, mutect2, varscan2
- WDR27 | c.882G>A p.K294= | Silent (SNP) | VAF 48/340 reads (14%) | called by muse, mutect2
- WDR6 | c.1581C>T p.D527= | Silent (SNP) | VAF 116/729 reads (16%) | called by muse, mutect2, varscan2
- WNK4 | c.1449C>T p.D483= | Silent (SNP) | VAF 119/596 reads (20%) | called by muse, mutect2, varscan2
- WRN | c.1857T>C p.L619= | Silent (SNP) | VAF 48/354 reads (14%) | called by muse, mutect2
- ZNF358 | c.984C>T p.F328= | Silent (SNP) | VAF 126/827 reads (15%) | catalogued as COSV51173834; called by muse, mutect2, varscan2
- ZNF592 | c.3501C>T p.S1167= | Silent (SNP) | VAF 88/593 reads (15%) | called by muse, varscan2
- ZNF732 | c.747T>C p.S249= | Silent (SNP) | VAF 67/383 reads (17%) | catalogued as rs1553837771; called by muse, mutect2, varscan2
- ZNF805 | c.990C>T p.F330= | Silent (SNP) | VAF 84/543 reads (15%) | catalogued as COSV62832489; called by muse, mutect2, varscan2
- AC092070.2 | n.1576C>T | RNA (SNP) | VAF 43/340 reads (13%) | called by muse, mutect2, varscan2
- CARD16 | c.274+851G>A | Intron (SNP) | VAF 48/339 reads (14%) | catalogued as rs1139550; called by muse, mutect2, varscan2
- CFAP65 | c.542+22G>A | Intron (SNP) | VAF 118/500 reads (24%) | called by muse, mutect2, varscan2
- COL14A1 | c.*458A>G | 3'UTR (SNP) | VAF 68/299 reads (23%) | called by muse, mutect2, varscan2
- CUX1 | chr7:101816076 G>A | 5'Flank (SNP) | VAF 58/351 reads (17%) | called by muse, mutect2, varscan2
- DYRK4 | chr12:4589000 A>C | 5'Flank (SNP) | VAF 61/351 reads (17%) | called by muse, mutect2, varscan2
- FOXA1 | c.-219C>T | 5'UTR (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- FOXA1 | c.-220C>T | 5'UTR (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+36188C>T | Intron (SNP) | VAF 44/307 reads (14%) | catalogued as rs933093799; called by muse, mutect2, varscan2
- LINC02269 | n.553G>A | RNA (SNP) | VAF 80/433 reads (18%) | catalogued as rs749148859; called by muse, mutect2, varscan2
- LRRC1 | c.446+983C>G | Intron (SNP) | VAF 73/482 reads (15%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-802G>A | Intron (SNP) | VAF 295/971 reads (30%) | catalogued as COSV58516701; called by muse, mutect2, varscan2
- PCDHA9 | c.2394+46G>A | Intron (SNP) | VAF 47/293 reads (16%) | called by muse, mutect2, varscan2
- TINAG | c.624+10C>T | Intron (SNP) | VAF 104/572 reads (18%) | called by muse, varscan2
- TINAG | c.624+11C>T | Intron (SNP) | VAF 103/567 reads (18%) | called by muse, varscan2
- TRMT9B | chr8:13031126 C>T | 3'Flank (SNP) | VAF 46/249 reads (18%) | called by muse, mutect2, varscan2
- XIST | n.8254C>T | RNA (SNP) | VAF 53/167 reads (32%) | called by muse, mutect2, varscan2
- ZC3H14 | c.1280-1763C>T | Intron (SNP) | VAF 67/387 reads (17%) | catalogued as COSV99193058; called by muse, mutect2, varscan2
- ZNF333 | c.511+1626C>T | Intron (SNP) | VAF 63/364 reads (17%) | called by muse, mutect2, varscan2
- ZNF333 | c.511+1627C>T | Intron (SNP) | VAF 63/366 reads (17%) | catalogued as rs1290270312; called by muse, mutect2, varscan2
